Gene-level copy-number profile of tumor specimen C3N-02335-02 from CPTAC case C3N-02335, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IA; Age at diagnosis: 69.1 years (25,246 days).
Specimen C3N-02335-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Skin; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file edb6a4b6-15c7-45f5-9158-d492e3341067.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-02335-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,715 have no estimate.
https://portal.gdc.cancer.gov/files/2ef8130a-8167-45f2-8cba-7b3e73e2474e

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 236; copy number 1: 2,099; copy number 2: 16,258; copy number 3: 28,825; copy number 4: 5,623; copy number 5: 3,226; copy number 6: 878; copy number 7: 459; copy number 8: 120; copy number 9: 136; copy number 10: 45; copy number 11: 23; copy number 12: 47; copy number 13: 59; copy number 14: 102; copy number 15: 241; copy number 16: 66; copy number 17: 161; copy number 18: 61; copy number 19: 32; copy number 20: 40; copy number 22: 30; copy number 24: 23; copy number 26: 16; copy number 27: 54; copy number 28: 2; copy number 30: 4; copy number 31: 13; copy number 32: 1; copy number 33: 1; copy number 34: 22; copy number 37: 5.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,763 genes in 30 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,486,926–49,589,529, 12 genes, copy number 9: AC119751.3, ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.
- chr5:31,532,287–31,559,875, 2 genes, copy number 7: C5orf22, AC022417.1.
- chr5:38,556,765–38,685,126, 3 genes, copy number 7 (within-gene range 6–7): LIFR-AS1, MIR3650, AC010425.1.
- chr6:44,089,242–44,450,425, 18 genes, copy number 7: AL109615.1, MRPL14, TMEM63B, CAPN11, RN7SL811P, MYMX, SLC29A1, HSP90AB1, SLC35B2, MIR4647, NFKBIE, TMEM151B, AL353588.1, TCTE1, AARS2, SPATS1, CDC5L, MIR4642.
- chr8:58,411,359–60,623,644, 26 genes, copy number 8: UBXN2B, AC009927.1, CYP7A1, PPIAP85, SDCBP, NSMAF, AC068522.1, TOX, RNU4-50P, AC105150.1, AC090152.1, AC087698.1, RNA5SP267, AC087664.3, AC087664.1, AC087664.2, AC107934.1, AC107934.2, AC022709.1, AC021393.1, SLC2A13P1, CA8, LINC01301, PDCL3P1, RAB2A, AC068389.3.
- chr8:60,906,059–63,609,600, 40 genes, copy number 8: IFITM3P8, AC022182.1, NASPP1, AC022182.2, CLVS1, NPM1P6, AC023866.2, AC023866.1, ASPH, KRT8P3, RN7SKP97, MIR4470, AC091173.1, LINC02842, AC025524.1, LINC02155, C1GALT1P3, NARS1P2, AC104852.1, AC023095.1, NKAIN3, AC018861.2, AC018861.1, AC090577.1, XRCC6P4, SRPK2P, AC120042.1, GGH, AC120042.2, TTPA, AC011978.1, YTHDF3-AS1, YTHDF3, AC011978.2, RN7SL135P, AC011124.1, IFITM8P, AC011124.2, AC018953.1, RN7SKP135.
- chr8:77,399,072–95,993,103, 278 genes, copy number 7 (broad region; genes not listed).
- chr8:98,189,826–99,877,580, 30 genes, copy number 7 (within-gene range 5–7): NIPAL2, RNU6-914P, STK3, AP003355.3, AP003355.1, KCNS2, AP003355.2, RNU6-748P, AP003467.1, AP003467.2, RPL19P14, AC016877.2, MRPL57P7, RN7SKP85, AC016877.3, OSR2, VPS13B-DT, AC016877.1, AC104986.1, VPS13B, AC107909.2, AC107909.1, AP004290.1, AP004289.2, AP004289.1, Y_RNA, MIR599, MIR875, RN7SL350P, AC018442.1.
- chr11:66,278,175–82,970,584, 479 genes, copy number 8–37 (within-gene range 2–37) (broad region; genes not listed).
- chr11:89,764,884–90,915,052, 42 genes, copy number 7 (within-gene range 3–15): AP003122.3, AP003122.1, TRIM64DP, AP004833.2, AP004833.3, TRIM49, AP004833.1, TRIM53BP, TRIM51BP, AP005435.1, TRIM64B, AP005435.4, AP005435.2, AP005435.3, MTND1P35, TRIM49D1, TRIM49D2, AP004607.3, AP004607.9, AP004607.8, AP004607.1, TRIM64, AP004607.7, TRIM51EP, TRIM53AP, AP004607.6, TRIM49C, AP004607.2, AP004607.4, TRIM64EP, AP004607.5, AP000827.1, UBTFL1, AP000648.2, AP000648.1, AP000648.3, NAALAD2, AP000648.4, CHORDC1, AP002364.1, DISC1FP1, TUBAP2.
- chr11:90,731,110–91,950,034, 13 genes, copy number 7–15: AP002782.1, MIR1261, AP001002.3, AP001002.1, AP001002.2, OSBPL9P2, OSBPL9P3, LINC02748, AP003485.2, AP003485.1, AP002791.1, LINC02756, TUBB4BP4.
- chr11:92,336,032–94,114,208, 53 genes, copy number 15: NDUFB11P1, FAT3, PGAM1P9, AP000722.1, RPS3AP42, AP003718.1, LINC02746, AP003171.2, SNRPGP16, AP003171.1, MTNR1B, RPL26P31, AP002371.1, AP003072.4, SLC36A4, AP003072.2, AP003072.5, AP003072.3, AP003072.1, AP003969.1, AP003969.2, DEUP1, SMCO4, SRP14P2, RN7SL223P, AP003499.5, AP003499.4, AP003499.1, CEP295, Y_RNA, SCARNA9, AP003499.3, AP003499.2, AP001273.1, TAF1D, SNORA25, SNORA32, SNORD6, SNORA1, SNORA8, SNORD5, SNORA18, MIR1304, SNORA40, C11orf54, AP001273.2, MED17, VSTM5, Y_RNA, AP002795.1, HPRT1P3, HEPHL1, PHBP16.
- chr11:94,185,439–94,282,203, 1 gene, copy number 15 (within-gene range 3–15): AP002784.1.
- chr11:94,305,592–96,389,956, 45 genes, copy number 15: IZUMO1R, GPR83, MRE11, MIR548L, AP000786.1, ANKRD49, C11orf97, FUT4, PIWIL4, AP000943.2, AP000943.3, AP000943.1, LINC02700, AMOTL1, AP002383.2, ST13P11, CWC15, KDM4D, AP002383.1, KDM4E, AP002383.5, AP002383.3, AP002383.4, KDM4F, AP001264.1, SRSF8, ENDOD1, BUD13P1, AP000787.2, AP000787.1, SESN3, AP000787.3, AP001790.1, AP000820.2, AP000820.1, AP001877.1, FAM76B, CEP57, MTMR2, RNA5SP345, AP000870.1, MAML2, AP000779.1, MIR1260B, CCDC82.
- chr11:107,326,345–107,963,482, 12 genes, copy number 7–9: CWF19L2, SMARCE1P1, ALKBH8, AP001823.1, ELMOD1, AP000889.2, AP000889.1, SLN, AP002353.1, SLC35F2, AP001024.1, RAB39A.
- chr12:24,566,964–24,949,101, 7 genes, copy number 11 (within-gene range 5–11): LINC00477, KNOP1P1, AC087312.1, AC023796.1, RN7SL38P, BCAT1, AC023796.2.
- chr13:42,040,036–42,256,578, 1 gene, copy number 11 (within-gene range 5–11): DGKH.
- chr13:42,181,465–43,786,908, 19 genes, copy number 7–11: CHCHD2P11, FHP1, AKAP11, LINC02341, FABP3P2, TNFSF11, FAM216B, LINC01050, LINC00428, EPSTI1, ZDHHC4P1, DNAJC15, LINC00400, AL138709.1, ENOX1, RPL36P19, ENOX1-AS2, ENOX1-AS1, AL161714.1.
- chr22:18,178,038–19,783,593, 78 genes, copy number 15 (within-gene range 3–15) (broad region; genes not listed).
- chr22:19,941,371–27,920,134, 437 genes, copy number 8–24 (within-gene range 2–24) (broad region; genes not listed).
- chr22:27,919,384–27,919,545, 1 gene, copy number 14 (within-gene range 2–14): AL031591.2.
- chr22:34,017,422–34,218,796, 1 gene, copy number 14 (within-gene range 2–14): LINC01643.
- chr22:35,501,861–36,387,967, 29 genes, copy number 7–14 (within-gene range 7–19): AL022334.1, AL022334.2, RASD2, MB, AL049747.1, APOL6, AL049748.1, MRPS16P3, APOL5, RBFOX2, NDUFA9P1, Z82217.1, Z95114.4, Z95114.1, Z95114.2, Z95114.3, APOL3, MTCO1P20, MTCO2P20, MTATP6P20, MTCO3P20, MTCYBP34, MTND1P10, APOL4, APOL2, APOL1, MYH9, MIR6819, Z82215.1.
- chr22:36,510,855–37,666,932, 45 genes, copy number 7–8: EIF3D, AL022313.1, AL022313.3, CACNG2, AL022313.4, AL049749.1, IFT27, Z80897.1, PVALB, Z82185.1, NCF4-AS1, NCF4, CSF2RB, CSF2RBP1, LL22NC01-81G9.3, TEX33, TST, Y_RNA, MPST, KCTD17, RN7SKP214, TMPRSS6, AL022314.1, IL2RB, Z82188.2, C1QTNF6, SSTR3, Z82188.1, RAC2, CYTH4, ELFN2, Z94160.1, ELFN2, Z94160.2, MFNG, CARD10, AL022315.1, CDC42EP1, LGALS2, Metazoa_SRP, GGA1, SH3BP1, Z83844.2, PDXP-DT, PDXP.
- chr22:39,399,778–39,532,761, 7 genes, copy number 7: TAB1, MGAT3, MGAT3-AS1, MIEF1, AL022312.1, ATF4, RPS19BP1.
- chr22:41,045,497–41,286,187, 15 genes, copy number 12: Y_RNA, AL080243.2, Y_RNA, AL080243.1, MIR1281, EP300, RNU6-375P, AL035658.1, EP300-AS1, LRRC37A14P, L3MBTL2, L3MBTL2-AS1, CHADL, RANGAP1, MIR6889.
- chr22:41,621,163–42,369,284, 40 genes, copy number 13: XRCC6, Y_RNA, SNU13, Z83840.1, RNU6-476P, C22orf46, MEI1, HMGN2P10, RNU6ATAC22P, Y_RNA, CCDC134, SREBF2-AS1, SREBF2, MIR33A, SHISA8, TNFRSF13C, MIR378I, CENPM, LINC00634, SEPTIN3, Z99716.1, WBP2NL, SLC25A5P1, NAGA, PHETA2, SNORD13P1, SMDT1, NDUFA6, AL021878.4, NDUFA6-DT, OLA1P1, CYP2D6, AC254562.1, AC254562.2, AC254562.3, CYP2D7, CYP2D8P, TCF20, OGFRP1, LINC01315.
- chr22:43,516,107–44,366,284, 18 genes, copy number 9–13 (within-gene range 2–13): EFCAB6-AS1, EFCAB6, Z97055.1, HMGN2P9, Z97055.2, SULT4A1, PNPLA5, PNPLA3, SAMM50, RPL35AP36, PARVB, AL033543.1, AL031595.3, PARVG, AL031595.1, AL031595.2, SHISAL1, Z85994.1.
- chr22:44,881,162–45,010,005, 1 gene, copy number 9 (within-gene range 2–9): PHF21B.
- chr22:45,000,565–45,295,874, 10 genes, copy number 9: AL079301.1, NUP50-DT, Z82243.1, NUP50, AL008718.3, KIAA0930, MIR1249, AL008718.2, AL008718.1, UPK3A.

Autosomal genes at a single copy (total copy number 1): 1,776. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
